Somatic mutation profile of tumor specimen TCGA-5C-A9VH-01A (aliquot TCGA-5C-A9VH-01A-11D-A36X-10) from TCGA case TCGA-5C-A9VH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.1 years (25,608 days).
Specimen TCGA-5C-A9VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eb50297-97f2-4862-950f-d9de9a1ca0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5C-A9VH-10A (Blood Derived Normal), aliquot TCGA-5C-A9VH-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a47c449c-b81e-4d21-8415-642cc2b2cb9a

The open-access MAF lists 107 somatic variants for this specimen: 89 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 78, Silent 18, Frame Shift Del 6, Nonsense Mutation 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC090517.4 | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV99974413; called by muse, mutect2, varscan2
- ATAD5 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100429920; called by muse, mutect2, varscan2
- BEND4 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV72469350; called by muse, mutect2, varscan2
- BLID | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as COSV101601718; called by muse, mutect2, varscan2
- BPIFA2 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs542770426, COSV99487861; called by muse, mutect2, varscan2
- CBX4 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99490321; called by muse, mutect2, varscan2
- CDK18 | c.370A>G p.S124G (on ENST00000506784 / NM_212503.3; = p.S94G on NM_002596.4) | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100773993; called by muse, mutect2, varscan2
- CFAP58 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV63835229; called by muse, mutect2, varscan2
- COL6A3 | c.7142A>G p.Q2381R | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.164); catalogued as COSV99797923; called by muse, mutect2, varscan2
- COP1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs982005070, COSV100443185; called by muse, mutect2
- CSAD | c.133G>C p.E45Q (on ENST00000444623 / NM_001244705.2; = p.E72Q on NM_015989.5) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV99914689; called by muse, mutect2, varscan2
- CSPG4 | c.6661A>G p.N2221D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100413733; called by muse, mutect2, varscan2
- CTDP1 | c.1384A>T p.S462C | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99310482; called by muse, mutect2, varscan2
- DAZAP2 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV101199391; called by muse, mutect2, varscan2
- DDIT4 | c.155C>G p.S52W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100259100; called by muse, mutect2, varscan2
- DLGAP4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs374922768, COSV59420286; called by muse, mutect2, varscan2
- DUOXA2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV99973131; called by muse, mutect2, varscan2
- EMC1 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100916440; called by muse, mutect2, varscan2
- ESAM | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99631783; called by muse, mutect2, varscan2
- EZHIP | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV100539625; called by muse, mutect2
- FGD5 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99547945; called by muse, mutect2, varscan2
- FLAD1 | c.1349A>T p.Q450L | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV99422436; called by muse, mutect2, varscan2
- FMO2 | c.1186T>C p.L396= | Splice Region (SNP) | VAF 92/393 reads (23%) | catalogued as COSV99269095; called by muse, mutect2, varscan2
- GABRQ | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 81/111 reads (73%) | catalogued as COSV100941220, COSV64781520; called by muse, mutect2, varscan2
- GLP1R | c.1208G>A p.C403Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100952568; called by muse, mutect2, varscan2
- GLP1R | c.1209C>A p.C403* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100952569; called by muse, mutect2, varscan2
- GLYR1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100424222; called by muse, mutect2, varscan2
- GP2 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100221459; called by muse, mutect2, varscan2
- GSTCD | c.1799G>T p.R600L (on ENST00000360505 / NM_001031720.3; = p.R513L on NM_024751.3) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853827; called by muse, mutect2, varscan2
- HELZ | c.1376G>C p.R459P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100698667, COSV62378285, COSV62381429; called by muse, mutect2, varscan2
- HIRA | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99600299; called by muse, mutect2, varscan2
- IFNB1 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207798; called by muse, mutect2, varscan2
- ITFG1 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278699; called by muse, mutect2, varscan2
- JRK | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs782347045, COSV70630469; called by muse, mutect2, varscan2
- KCNMB3 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV99836959; called by muse, mutect2
- KIF26B | c.6175G>C p.E2059Q | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as COSV100832250; called by muse, mutect2, varscan2
- KMT2C | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV100071231, COSV51522248; called by muse, mutect2, varscan2
- LTBP4 | c.3820G>A p.A1274T (on ENST00000308370 / NM_001042544.1; = p.A1237T on NM_003573.2) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.527); catalogued as COSV99180819; called by muse, mutect2, varscan2
- MCM4 | c.1823A>T p.N608I | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50626574; called by muse, mutect2, varscan2
- MFRP | c.3C>A p.*1= (on ENST00000449574; = p.P383= on NM_031433.4) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs1192613446, COSV100793421; called by muse, mutect2, varscan2
- MRGPRX4 | c.272G>C p.S91T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100049712; called by muse, mutect2, varscan2
- MYCBP2 | c.1492G>A p.A498T (on ENST00000357337; = p.A536T on NM_015057.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62043098; called by muse, mutect2, varscan2
- NBEAL1 | c.5776G>A p.G1926R | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV101355484; called by muse, mutect2, varscan2
- NCAM2 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99522791; called by muse, mutect2, varscan2
- NFIC | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1043201283, COSV100545290; called by muse, mutect2, varscan2
- NOTCH4 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs765988217, COSV100900364; called by muse, mutect2
- OR1S1 | c.851A>T p.D284V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100515368; called by muse, mutect2, varscan2
- OR2C3 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100825673; called by muse, mutect2, varscan2
- PCDH1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs752422297, COSV54616747; called by muse, mutect2, varscan2
- PCDH11Y | c.1850G>A p.R617K (on ENST00000400457 / NM_032973.2; = p.R606K on NM_032971.3) | Missense Mutation (SNP) | VAF 101/137 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99291294; called by muse, mutect2, varscan2
- PCDHB12 | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99507183; called by muse, mutect2, varscan2
- PHLPP1 | c.2459G>C p.R820T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99408095; called by muse, mutect2
- PKD1L2 | c.1325T>C p.I442T | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV100449847; called by muse, mutect2, varscan2
- PLEKHG2 | c.3883G>C p.G1295R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99217339; called by muse, mutect2
- PLPPR3 | c.1339G>A p.E447K (on ENST00000520876 / NM_001270366.2; = p.E475K on NM_024888.2) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.179); catalogued as rs1335171754, COSV100608617; called by muse, mutect2, varscan2
- PODXL | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201501253, COSV59870467; called by muse, mutect2, varscan2
- PRKG1 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64772494; called by muse, mutect2, varscan2
- PROC | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99300760; called by muse, mutect2, varscan2
- PRRT1 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99278397, COSV99278548; called by muse, mutect2, varscan2
- RAI14 | c.1664_1665del p.E555Vfs*15 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs1561088297; called by pindel, varscan2
- RNF17 | c.1978T>A p.F660I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99693035; called by muse, mutect2, varscan2
- SDAD1 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV62403344; called by muse, varscan2
- SEMA4F | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs747881367, COSV60284777; called by muse, mutect2, varscan2
- SH3PXD2A | c.3232G>A p.V1078I (on ENST00000369774 / NM_001365079.1; = p.V1050I on NM_014631.2) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs561681082, COSV60118740; called by muse, mutect2, varscan2
- SHISA5 | c.314+1G>A p.X105_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as rs781661394, COSV99604556; called by muse, mutect2, varscan2
- SLC17A3 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100399188; called by muse, mutect2, varscan2
- SMAD4 | c.1569C>G p.C523W | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100747628, COSV100748170, COSV61684051; called by muse, mutect2, varscan2
- SORBS2 | c.2107C>A p.P703T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99510692; called by muse, mutect2, varscan2
- SPATA7 | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV99247935; called by muse, mutect2, varscan2
- SRGAP1 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100754620; called by muse, mutect2, varscan2
- ST8SIA6 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66466994; called by muse, mutect2, varscan2
- STK32B | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99285479; called by muse, mutect2, varscan2
- TACR3 | c.41del p.G14Vfs*9 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as COSV59209981; called by mutect2, pindel, varscan2
- TAS2R20 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV101114699; called by muse, mutect2, varscan2
- TBX19 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100892347; called by muse, mutect2, varscan2
- TGFB2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV100860082; called by muse, mutect2, varscan2
- TIGD5 | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV99643439; called by muse, mutect2, varscan2
- TMEM174 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV57113435, COSV99703769; called by muse, mutect2, varscan2
- TNS3 | c.1548C>A p.S516R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100235449; called by muse, mutect2, varscan2
- TRAT1 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753534244, COSV99849234; called by muse, mutect2, varscan2
- TTN | c.16174T>C p.C5392R (on ENST00000591111; = p.C4465R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | PolyPhen probably damaging (0.998); catalogued as COSV100610347; called by muse, mutect2, varscan2
- VPS4A | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256093452, COSV99651926; called by muse, mutect2
- ZNF384 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV100158444; called by muse, mutect2, varscan2
- CHRM1 | c.646_650del p.E216Pfs*32 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | called by mutect2, pindel, varscan2
- GDNF | c.44del p.H15Pfs*33 | Frame Shift Del (DEL) | VAF 45/161 reads (28%) | called by mutect2, pindel, varscan2
- ITPKB | c.1334del p.G445Efs*44 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- SOCS7 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.961); called by muse, varscan2
- SOCS7 | c.606C>G p.S202R | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZSCAN16 | c.217_226del p.E73Pfs*6 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- BRCA1 | c.771T>C p.H257= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100524033; called by muse, mutect2, varscan2
- C19orf57 | c.141G>A p.E47= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV100694692; called by muse, mutect2, varscan2
- EDN1 | c.129A>G p.P43= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV101040358; called by muse, varscan2
- FCER2 | c.93C>A p.T31= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV100689561; called by muse, mutect2, varscan2
- FILIP1 | c.2298G>A p.G766= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV52744294; called by muse, mutect2, varscan2
- GABRR3 | c.1233G>A p.S411= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs1252352597, COSV72115920; called by muse, mutect2, varscan2
- HENMT1 | c.999C>T p.F333= | Silent (SNP) | VAF 49/75 reads (65%) | catalogued as COSV100898656; called by muse, mutect2, varscan2
- HEPACAM | c.1011G>A p.P337= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV100005670; called by muse, mutect2, varscan2
- HIVEP1 | c.1218T>C p.Y406= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs770339091, COSV101045103; called by muse, mutect2, varscan2
- OLFM4 | c.237C>T p.D79= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99524299; called by muse, mutect2, varscan2
- PAPPA2 | c.1260T>C p.R420= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV100866763; called by muse, mutect2, varscan2
- PIGW | c.492A>G p.T164= | Silent (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- RNF112 | c.651C>A p.G217= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV101518342; called by muse, mutect2, varscan2
- ROBO2 | c.96G>A p.R32= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV59922593; called by muse, mutect2, varscan2
- UBAP2L | c.222C>T p.D74= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99671104; called by muse, mutect2, varscan2
- UPRT | c.321G>T p.G107= | Silent (SNP) | VAF 81/96 reads (84%) | catalogued as COSV100974487; called by muse, mutect2, varscan2
- VPS45 | c.756G>T p.V252= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as rs375831361; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR19 | c.4026G>C p.L1342= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as COSV99975420; called by muse, mutect2, varscan2
